Somatic mutation profile of tumor specimen TCGA-E7-A3Y1-01A (aliquot TCGA-E7-A3Y1-01A-11D-A22Z-08) from TCGA case TCGA-E7-A3Y1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 57.3 years (20,917 days).
Specimen TCGA-E7-A3Y1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75254525-58b5-4e66-af47-e19dfb01e1f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A3Y1-10A (Blood Derived Normal), aliquot TCGA-E7-A3Y1-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b5af67f-514a-4d74-b665-80f4ec34e7ba

The open-access MAF lists 181 somatic variants for this specimen: 127 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 48, Frame Shift Del 13, Nonsense Mutation 11, Splice Site 5, Intron 2, RNA 2, 5'UTR 1, 3'UTR 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*164G>T | 3'UTR (SNP) | VAF 98/262 reads (37%) | catalogued as rs121913479, CM960656, COSV53390089, COSV99600444; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABT1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV51290841; called by muse, mutect2, varscan2
- ADAMTS12 | c.3577G>C p.E1193Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV61258876, COSV61279501; called by muse, varscan2
- ADAMTS12 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61258883, COSV61283550; called by muse, mutect2
- ADAMTS14 | c.3595C>G p.P1199A | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV64600777; called by muse, mutect2, varscan2
- ADAMTS6 | c.3257T>C p.V1086A | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as COSV58682196; called by muse, mutect2, varscan2
- ADGRL1 | c.1094C>G p.P365R (on ENST00000340736 / NM_001008701.3; = p.P360R on NM_014921.5) | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV61564092; called by muse, mutect2
- AIFM3 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53146213; called by muse, mutect2
- AKAP1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV58469228; called by muse, mutect2, varscan2
- ANKRD55 | c.700T>C p.C234R | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1422903504, COSV61945735; called by muse, mutect2, varscan2
- AP1B1 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs747391498, COSV58015718; called by muse, mutect2
- ATCAY | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV104397708, COSV56656178; called by muse, mutect2, varscan2
- ATG4D | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as rs765478983, COSV57264091; called by muse, mutect2, varscan2
- ATP8A1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357805168, COSV100045253, COSV52531376; called by muse, mutect2, varscan2
- BMX | c.1020T>A p.N340K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV59590742; called by muse, mutect2, varscan2
- BNIPL | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV54846352; called by muse, mutect2, varscan2
- CACNG7 | c.425-2A>G p.X142_splice | Splice Site (SNP) | VAF 11/154 reads (7%) | catalogued as COSV55813709; called by muse, mutect2
- CELF6 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1422114535; called by muse, mutect2
- CHD1 | c.1565A>G p.Y522C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52338776; called by muse, mutect2
- CHKB | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1569054080, COSV56415823, COSV56415867; called by muse, mutect2, varscan2
- CNBD1 | c.331A>T p.I111L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV72916776; called by muse, mutect2, varscan2
- CNTN5 | c.1439C>A p.P480H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54294365; called by muse, mutect2, varscan2
- COL1A2 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV51957026; called by muse, mutect2
- COL22A1 | c.4466C>T p.P1489L | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs757031031, COSV57329821, COSV57366824; called by muse, mutect2, varscan2
- COL4A4 | c.3472del p.D1158Ifs*10 | Frame Shift Del (DEL) | VAF 38/132 reads (29%) | catalogued as COSV61629657, COSV61629917; called by mutect2, pindel, varscan2
- COL5A3 | c.2957G>A p.G986E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53408269; called by muse, mutect2, varscan2
- CSMD2 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53895032; called by muse, mutect2
- CYP4F2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs1418098189, COSV55617077; called by muse, mutect2, varscan2
- DAPK2 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV56044481; called by muse, mutect2, varscan2
- DDI1 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV56372274; called by muse, mutect2, varscan2
- DENND3 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as rs1387720665, COSV52801662; called by muse, mutect2
- DNAAF2 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV53568361; called by muse, mutect2, varscan2
- DNAH5 | c.10042C>T p.P3348S | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV54213526; called by muse, mutect2
- DNASE1L3 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV59155450, COSV59155486; called by muse, mutect2, varscan2
- EPHA8 | c.1703G>T p.C568F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.915); catalogued as COSV51265203; called by muse, mutect2, varscan2
- ESYT2 | c.2565-1G>A p.X855_splice (on ENST00000613624; = p.X779_splice on NM_020728.3) | Splice Site (SNP) | VAF 67/153 reads (44%) | catalogued as rs191388596, COSV51749424; called by muse, mutect2, varscan2
- EXOSC9 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV54665407; called by muse, mutect2, varscan2
- F5 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 99/339 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs375248946; called by muse, mutect2, varscan2
- FAT4 | c.4291G>C p.E1431Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67883205; called by muse, mutect2
- FBP1 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV64688987; called by muse, mutect2, varscan2
- FER1L6 | c.4956C>A p.N1652K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67548932, COSV67551935; called by muse, mutect2, varscan2
- GABBR1 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63541692; called by muse, mutect2, varscan2
- GRM5 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV100551277; called by mutect2, varscan2
- HIPK2 | c.538A>T p.S180C | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV61226582; called by muse, mutect2, varscan2
- IQCF1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV58823249; called by muse, mutect2, varscan2
- ITIH4 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV56572540, COSV99819357; called by muse, mutect2, varscan2
- KHDRBS2 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV55438044; called by muse, mutect2, varscan2
- KLF5 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613932, COSV66614001; called by muse, mutect2, varscan2
- KLHL15 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 82/100 reads (82%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV60139622; called by muse, mutect2, varscan2
- KMT2C | c.7098del p.D2366Efs*6 | Frame Shift Del (DEL) | VAF 32/70 reads (46%) | catalogued as COSV51422080; called by mutect2, pindel, varscan2
- KNDC1 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100464491, COSV58833843; called by muse, mutect2, varscan2
- KRT6C | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.567); catalogued as COSV52877058; called by muse, mutect2, varscan2
- KRT75 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs1444521517, COSV52871736; called by muse, mutect2
- KRTAP10-11 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs782557322, COSV58177428; called by muse, mutect2, varscan2
- LRRC66 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs527846401, COSV100602767, COSV58632301; called by muse, mutect2, varscan2
- MBD1 | c.742del p.R248Afs*74 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as COSV53998320; called by mutect2, pindel, varscan2
- MPHOSPH10 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV54905490; called by muse, mutect2, varscan2
- MPP7 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780355716, COSV100517229; called by muse, mutect2, varscan2
- MPP7 | c.1124-1G>T p.X375_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100517231; called by muse, mutect2, varscan2
- MSLN | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV67018934; called by muse, mutect2, varscan2
- MTNR1A | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56155498; called by muse, mutect2, varscan2
- MXD4 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1386992623; called by muse, mutect2
- NFATC2IP | c.476A>T p.D159V | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV57909965; called by muse, mutect2, varscan2
- NOTCH1 | c.5913_5925del p.D1972Sfs*5 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as COSV53039002; called by pindel, varscan2
- NOTCH1 | c.4587C>T p.N1529= | Splice Region (SNP) | VAF 18/37 reads (49%) | catalogued as COSV53034334, COSV53039041; called by muse, mutect2, varscan2
- NPR3 | c.1589G>A p.R530Q (on ENST00000265074 / NM_001364458.2; = p.R529Q on NM_000908.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1165329273, COSV54094306; called by muse, mutect2, varscan2
- OR1A2 | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV67936255, COSV67936729; called by muse, mutect2, varscan2
- OR2L8 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100594122, COSV61726113; called by muse, mutect2, varscan2
- OR4F6 | c.694G>C p.G232R | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV61026475; called by muse, mutect2, varscan2
- OR4N2 | c.788G>T p.R263M | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV60050661; called by muse, mutect2, varscan2
- PANX3 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV52511495; called by muse, mutect2, varscan2
- PAPPA | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); catalogued as rs867538153, COSV60279940; called by muse, mutect2, varscan2
- PARP8 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55858132; called by muse, mutect2, varscan2
- PCDHB10 | c.1802G>A p.W601* | Nonsense Mutation (SNP) | VAF 59/196 reads (30%) | catalogued as COSV99504070; called by muse, mutect2, varscan2
- PCDHGB2 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as COSV53919296; called by muse, mutect2
- PGAP1 | c.324del p.R110Efs*17 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as COSV61324954; called by mutect2, pindel, varscan2
- PIK3CG | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as rs867282260, COSV100782716, COSV63249428; called by muse, mutect2, varscan2
- PINX1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs1442611009, COSV59108718; called by muse, mutect2, varscan2
- POLK | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV54033376; called by muse, mutect2, varscan2
- PTCH1 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs768956985, COSV59468127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGDS | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99811807; called by muse, mutect2
- QSER1 | c.1139G>T p.G380V (on ENST00000399302; = p.G509V on NM_001076786.3) | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV67899945; called by muse, mutect2, varscan2
- RBM22 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.614); catalogued as COSV52270973; called by muse, mutect2, varscan2
- SCN11A | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV100180664, COSV56566393; called by muse, mutect2
- SCN11A | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV56567798; called by muse, mutect2
- SH2D3C | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.931); catalogued as rs1564426824, COSV59120617; called by muse, mutect2
- SLCO1C1 | c.1006A>T p.M336L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56870325; called by muse, mutect2, varscan2
- SLU7 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51787140; called by muse, mutect2, varscan2
- SMG1 | c.7120C>T p.R2374* | Nonsense Mutation (SNP) | VAF 7/95 reads (7%) | catalogued as COSV67175104; called by muse, mutect2
- SNX13 | c.2174T>C p.M725T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV68064359; called by muse, mutect2, varscan2
- SPIC | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs539976810, COSV54690674; called by muse, mutect2
- SPRY4 | c.358G>T p.V120L (on ENST00000434127 / NM_001127496.3; = p.V143L on NM_030964.4) | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV59985640; called by muse, mutect2, varscan2
- STAB2 | c.2401A>G p.N801D | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV66336734; called by muse, mutect2, varscan2
- STAB2 | c.3692G>A p.S1231N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101185955, COSV66336742; called by muse, mutect2, varscan2
- STAG2 | c.1639-1G>A p.X547_splice | Splice Site (SNP) | VAF 31/39 reads (79%) | catalogued as COSV54354339; called by muse, mutect2, varscan2
- STUM | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64683840; called by muse, mutect2
- TAFA4 | c.131-1G>A p.X44_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as COSV55135517; called by muse, mutect2, varscan2
- TRAFD1 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV57503804; called by muse, mutect2, varscan2
- TRAV18 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs779187546; called by muse, mutect2, varscan2
- TSNARE1 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV56172934; called by muse, mutect2, varscan2
- TTC17 | c.2437G>A p.G813S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.473); catalogued as COSV50007036; called by muse, mutect2
- UNC79 | c.4513G>A p.G1505R (on ENST00000393151 / NM_001346218.2; = p.G1328R on NM_020818.5) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV56380381, COSV99830453; called by muse, mutect2, varscan2
- USH2A | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 97/162 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs3820464, COSV100234360, COSV56347017, COSV56379080; called by muse, mutect2, varscan2
- VARS1 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761390538, COSV63304368; called by muse, mutect2
- WDPCP | c.2147G>A p.C716Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772286167, COSV55415900; called by muse, mutect2, varscan2
- ZBTB41 | c.2398C>A p.Q800K | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100963473, COSV66358906; called by muse, mutect2, varscan2
- ZC3H6 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59666783; called by muse, mutect2, varscan2
- ZNF839 | c.1981G>A p.D661N (on ENST00000558850 / NM_001267827.1; = p.D777N on NM_018335.5) | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.174); catalogued as rs1029587209, COSV51756714; called by muse, mutect2
- AL592490.1 | c.1159G>T p.G387* | Nonsense Mutation (SNP) | VAF 60/162 reads (37%) | called by muse, mutect2, varscan2
- CST9 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 90/221 reads (41%) | called by muse, mutect2, varscan2
- DDX3X | c.1553_1555del p.P518_S519delinsR (on ENST00000399959; = p.P519_S520delinsR on NM_001356.5) | In Frame Del (DEL) | VAF 9/83 reads (11%) | called by mutect2, pindel
- DNAH8 | c.3898del p.W1300Gfs*4 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- DUOX2 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- FANCM | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- GPR179 | c.2479G>C p.G827R (on ENST00000621958; = p.G826R on NM_001004334.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- IGHG4 | c.146del p.G49Afs*21 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel
- KMT2D | c.13010del p.P4337Lfs*47 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- KMT2D | c.3979del p.A1327Pfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- MCTP1 | c.2046del p.D683Ifs*8 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- NEB | c.13394del p.G4465Afs*25 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- NID2 | c.3744G>A p.W1248* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- PCDH19 | c.1834dup p.R612Pfs*5 | Frame Shift Ins (INS) | VAF 34/54 reads (63%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.944G>A p.W315* | Nonsense Mutation (SNP) | VAF 28/456 reads (6%) | called by muse, mutect2
- RYR2 | c.3350G>A p.W1117* | Nonsense Mutation (SNP) | VAF 122/477 reads (26%) | called by muse, mutect2, varscan2
- SLC4A2 | c.305del p.P102Qfs*143 | Frame Shift Del (DEL) | VAF 47/128 reads (37%) | called by mutect2, pindel, varscan2
- TMEM132B | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- TRERF1 | c.837del p.Q280Nfs*53 | Frame Shift Del (DEL) | VAF 60/186 reads (32%) | called by mutect2, pindel, varscan2
- TULP3 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ADAM29 | c.252A>T p.T84= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV63662027; called by muse, mutect2, varscan2
- ADGRB1 | c.2841G>A p.P947= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs777364535, COSV60093854; called by muse, mutect2, varscan2
- AICDA | c.237C>T p.T79= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV57563777; called by muse, mutect2, varscan2
- BRSK1 | c.1641C>A p.A547= | Silent (SNP) | VAF 37/41 reads (90%) | catalogued as COSV58665496; called by muse, mutect2, varscan2
- CD109 | c.1092C>G p.L364= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs773650223, COSV54647315; called by muse, mutect2, varscan2
- CNTN5 | c.1440C>A p.P480= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV54294386; called by muse, mutect2, varscan2
- COL6A3 | c.2418A>G p.P806= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV55084258; called by muse, mutect2, varscan2
- CUBN | c.4935G>A p.Q1645= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs1340719524, COSV64711330; called by muse, mutect2, varscan2
- DBX1 | c.426C>T p.F142= | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as COSV57053404; called by muse, mutect2
- DDAH2 | c.96C>T p.G32= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as COSV65383772; called by muse, mutect2, varscan2
- DDIT4 | c.378G>A p.Q126= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV56577245; called by muse, mutect2, varscan2
- DYNC2H1 | c.10104C>G p.L3368= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV62089990; called by muse, mutect2, varscan2
- FLG | c.6651C>A p.A2217= | Silent (SNP) | VAF 215/1022 reads (21%) | catalogued as COSV64238969; called by muse, varscan2
- FNIP1 | c.2943A>G p.S981= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV57194889; called by muse, mutect2, varscan2
- GRM5 | c.792C>T p.L264= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs145650472; called by muse, mutect2, varscan2
- GTPBP6 | c.1318C>A p.R440= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100397724, COSV58204709; called by muse, mutect2, varscan2
- H1-2 | c.150C>T p.A50= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as rs150897775; called by muse, mutect2, varscan2
- HMCN1 | c.6447C>T p.G2149= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs759680774, COSV54887434; called by muse, mutect2, varscan2
- HMCN1 | c.16566C>T p.P5522= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs1376011200, COSV54887445; called by muse, mutect2, varscan2
- KARS1 | c.990G>A p.T330= | Silent (SNP) | VAF 90/240 reads (38%) | catalogued as rs776756075, COSV56691342, COSV56691847; called by muse, mutect2, varscan2
- KAT7 | c.261G>A p.V87= | Silent (SNP) | VAF 30/318 reads (9%) | catalogued as COSV52013628, COSV52015624; called by muse, mutect2
- KCNA5 | c.933G>A p.T311= | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as rs760147088, COSV52904641; called by muse, mutect2, varscan2
- KLHL34 | c.720T>C p.S240= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV65279006; called by muse, mutect2, varscan2
- KRT14 | c.123C>T p.R41= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs547482686; called by muse, varscan2
- LMOD3 | c.1422G>A p.Q474= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- LTBR | c.1056C>T p.G352= | Silent (SNP) | VAF 104/234 reads (44%) | catalogued as rs746664810, COSV57438561; called by muse, mutect2, varscan2
- MAP3K11 | c.885G>A p.K295= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs767622827, COSV58418889; called by muse, mutect2, varscan2
- MEGF10 | c.579G>A p.Q193= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as COSV57247200; called by muse, mutect2, varscan2
- MLXIP | c.2742G>A p.K914= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV59834451; called by muse, mutect2, varscan2
- MMP2 | c.1245A>G p.Q415= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV54599878; called by muse, mutect2, varscan2
- NCAM1 | c.2460G>A p.K820= (on ENST00000316851 / NM_181351.5; = p.K810= on NM_000615.7) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV57513340; called by muse, mutect2, varscan2
- NCAPH | c.2097C>T p.P699= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV53635666; called by muse, mutect2, varscan2
- NEDD9 | c.1755G>A p.Q585= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs1280268891, COSV65220109; called by muse, mutect2, varscan2
- ONECUT2 | c.654C>A p.P218= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV72203268; called by muse, mutect2, varscan2
- OR2W3 | c.141G>A p.L47= | Silent (SNP) | VAF 17/407 reads (4%) | catalogued as COSV64456444; called by muse, mutect2
- ORC3 | c.2121A>T p.T707= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV57639400; called by muse, mutect2, varscan2
- PCDHA2 | c.669G>A p.T223= | Silent (SNP) | VAF 66/139 reads (47%) | catalogued as COSV65365950; called by muse, mutect2, varscan2
- POTEE | c.2580C>T p.T860= | Silent (SNP) | VAF 81/242 reads (33%) | catalogued as COSV58227182, COSV58233301; called by muse, mutect2, varscan2
- PRKD1 | c.1599G>A p.E533= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV100120369, COSV59562787; called by muse, mutect2
- PSORS1C1 | c.225G>A p.Q75= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV52535247; called by muse, mutect2, varscan2
- RGS13 | c.363T>C p.F121= | Silent (SNP) | VAF 50/77 reads (65%) | catalogued as COSV67345810; called by muse, mutect2, varscan2
- RNPS1 | c.708C>T p.T236= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs952710974, COSV57043148; called by muse, mutect2, varscan2
- SEPTIN4 | c.1600C>T p.L534= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV100400403, COSV58727396; called by muse, mutect2, varscan2
- SLC10A1 | c.438T>C p.Y146= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as rs1483892781, COSV53682104; called by muse, mutect2, varscan2
- SLC16A5 | c.1194C>T p.F398= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV61675610; called by muse, mutect2, varscan2
- SLC35F4 | c.942C>T p.T314= (on ENST00000339762 / NM_001352015.2; = p.T278= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs376795716; called by muse, mutect2, varscan2
- SSRP1 | c.459C>T p.N153= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as rs774365460, COSV53478628; called by muse, mutect2, varscan2
- TIAM1 | c.2436A>G p.L812= | Silent (SNP) | VAF 90/186 reads (48%) | catalogued as COSV54543299; called by muse, mutect2, varscan2
- ASB16 | c.570-27C>T | Intron (SNP) | VAF 72/224 reads (32%) | catalogued as COSV53234398; called by muse, mutect2, varscan2
- LINC01559 | n.480C>T | RNA (SNP) | VAF 64/154 reads (42%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1380del | RNA (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- RPS3 | c.31-270G>C | Intron (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- ZDHHC23 | c.-1C>G | 5'UTR (SNP) | VAF 43/74 reads (58%) | catalogued as COSV57629054, COSV57630290; called by muse, mutect2, varscan2
